Somatic mutation profile of tumor specimen 0DI5F7 from CCDI case PBBUDW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tumor cells, malignant; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 4.6 years (1,689 days).
Specimen 0DI5F7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd2fa74f-8b04-44bd-97c8-58594301bca5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI5EC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb1f05d9-8c9f-4dd7-8320-10112a25eecc

The open-access MAF lists 31 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Intron 2, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 200/486 reads (41%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- CHD7 | c.6955C>A p.R2319S | Missense Mutation (SNP) | VAF 118/740 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs121434341, CM060217, CM060910; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 350/465 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.5465A>G p.N1822S | Missense Mutation (SNP) | VAF 633/1595 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs587781580, CD1413429; called by muse, mutect2, varscan2
- CSF1 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 198/586 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs377085953; called by muse, mutect2, varscan2
- INTS1 | c.5531C>T p.T1844M | Missense Mutation (SNP) | VAF 205/695 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs374496492, COSV101247409; called by muse, mutect2, varscan2
- KCNH8 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 377/1006 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1361265649; called by muse, mutect2, varscan2
- LGI4 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 223/404 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs762678784; called by muse, mutect2, varscan2
- PASK | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 188/474 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs556062263, COSV52149341; called by muse, mutect2, varscan2
- PRR23C | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 270/713 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV68827588; called by muse, mutect2, varscan2
- SYT5 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 134/458 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs1370060441; called by muse, mutect2, varscan2
- AJM1 | c.76_81del p.A26_S27del | In Frame Del (DEL) | VAF 68/288 reads (24%) | called by mutect2, varscan2
- CPA6 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 177/1045 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CPNE5 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.187); called by muse, varscan2
- FGFR4 | c.1603A>G p.N535D | Missense Mutation (SNP) | VAF 388/441 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FNDC3A | c.953A>G p.D318G (on ENST00000492622 / NM_001079673.2; = p.D262G on NM_014923.5) | Missense Mutation (SNP) | VAF 387/961 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GCNT3 | c.783A>C p.K261N | Missense Mutation (SNP) | VAF 53/446 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITSN1 | c.4205A>G p.D1402G | Missense Mutation (SNP) | VAF 263/683 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- KIAA1614 | c.1800_1806dup p.V603Rfs*19 | Frame Shift Ins (INS) | VAF 146/448 reads (33%) | called by mutect2, varscan2
- NAE1 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 342/905 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMU1 | c.765G>C p.Q255H | Missense Mutation (SNP) | VAF 451/1228 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPIDR | c.1666C>G p.Q556E | Missense Mutation (SNP) | VAF 293/1539 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- STX11 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 214/593 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- USP31 | c.3844C>A p.Q1282K | Missense Mutation (SNP) | VAF 236/615 reads (38%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DACT1 | c.1788C>T p.N596= | Silent (SNP) | VAF 255/608 reads (42%) | catalogued as rs1283092378; called by muse, mutect2, varscan2
- FMN1 | c.213C>T p.G71= | Silent (SNP) | VAF 234/774 reads (30%) | catalogued as rs796904990; called by muse, mutect2
- KIF21A | c.3732A>G p.R1244= (on ENST00000361418 / NM_001378440.1; = p.R1231= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 430/1900 reads (23%) | called by muse, mutect2, varscan2
- TENM3 | c.657G>A p.P219= | Silent (SNP) | VAF 553/1301 reads (43%) | catalogued as rs755058736; called by muse, mutect2, varscan2
- ANKRD24 | c.*58G>T | 3'UTR (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- DDX5 | c.44+263G>A | Intron (SNP) | VAF 1101/1655 reads (67%) | catalogued as rs1317881079; called by muse, mutect2
- MICAL3 | c.2801+43del | Intron (DEL) | VAF 62/140 reads (44%) | called by mutect2, varscan2
